Gene-level copy-number profile of tumor specimen TCGA-DX-A2J0-01A from TCGA case TCGA-DX-A2J0, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 61.2 years (22,369 days).
Specimen TCGA-DX-A2J0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.086b9671-9220-478d-9898-e46d449e4d56.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A2J0-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b4d46682-46af-448a-bf16-58e532d00c0d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 13,497; copy number 2: 44,551; copy number 3: 1,216; copy number 4: 107; copy number 5: 35; copy number 6: 5; copy number 7: 11; copy number 8: 23; copy number 9: 5; copy number 10: 34; copy number 11: 35; copy number 12: 38; copy number 13: 17; copy number 14: 55; copy number 15: 4; copy number 16: 19; copy number 17: 6; copy number 18: 38; copy number 19: 39; copy number 20: 23; copy number 24: 8; copy number 27: 1; copy number 28: 14; copy number 30: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A2J0-01A-11D-A21P-01): tumor purity 0.93, ploidy 1.88, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:31,094,927–31,382,116, 1 gene (within-gene range 0–1): NF1.
- chr17:31,272,013–31,538,211, 7 genes (within-gene range 0–1): OMG, EVI2B, AC134669.1, EVI2A, AK4P1, RAB11FIP4, RN7SL79P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 428 genes in 46 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:167,630,093–167,791,919, 2 genes, copy number 12 (within-gene range 1–12): RCSD1, MPZL1.
- chr1:167,916,675–168,137,667, 5 genes, copy number 13 (within-gene range 1–13): MPC2, DCAF6, MIR1255B2, GCSHP5, GPR161.
- chr1:171,248,471–172,468,831, 29 genes, copy number 11–12 (within-gene range 1–12): FMO1, Y_RNA, HMGB1P11, FMO4, TOP1P1, SRP14P4, GM2AP2, CYCSP53, PRRC2C, MYOCOS, MYOC, PFN1P1, RPL4P3, VAMP4, Z98751.1, Z98751.3, Z98751.2, AL135931.1, EEF1AKNMT, AL031864.1, AL031864.2, DNM3, DNM3-IT1, DNM3OS, MIR199A2, AL137157.1, RNU6-157P, PIGC, C1orf105.
- chr1:172,775,905–173,175,503, 6 genes, copy number 12: AL031599.1, AIMP1P2, Z97198.1, TNFSF18, GOT2P2, AL022310.1.
- chr1:175,877,343–175,922,145, 3 genes, copy number 9: LINC01657, LINC02803, RPS29P5.
- chr1:179,082,070–179,358,680, 11 genes, copy number 8 (within-gene range 1–8): TOR3A, ABL2, AL512326.5, SETP10, AL512326.2, AL512326.1, EIF4A1P11, AL512326.3, COX5BP8, AL512326.4, SOAT1.
- chr1:183,023,420–184,171,823, 20 genes, copy number 7–14: LAMC1, LAMC1-AS1, LAMC2, NMNAT2, AL354953.1, RPS3AP8, AL449223.1, SMG7-AS1, SMG7, NCF2, AL137800.1, ARPC5, RGL1, APOBEC4, AL157899.1, AL590422.1, COLGALT2, TSEN15, AL158011.1, Y_RNA.
- chr1:204,131,062–204,728,106, 24 genes, copy number 10: AL592146.1, ETNK2, ERLNC1, REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3, LRRN2, AL512306.2, AL161793.1, RNA5SP75, AL161793.2.
- chr1:230,820,250–230,824,707, 2 genes, copy number 8: RNA5SP79, AL118511.2.
- chr1:242,772,620–244,451,909, 33 genes, copy number 5: RSL24D1P4, AL445675.1, AL445675.2, AL603825.1, AL606534.3, SEPTIN14P21, CICP21, AL606534.4, LINC01347, RNU6-747P, CEP170, AL606534.1, AL606534.2, SDCCAG8, FCF1P7, MIR4677, AKT3, AL591721.1, FABP7P1, AL662889.1, AKT3-IT1, LINC02774, ZBTB18, AL590483.3, AL590483.1, AL590483.4, RN7SL148P, AL590483.2, AL358177.1, C1orf100, AL645465.1, TGIF2P1, ADSS2.
- chr9:69,818,394–70,354,873, 11 genes, copy number 8–19: C9orf135-DT, C9orf135, RN7SL570P, MAMDC2-AS1, MAMDC2, RNU2-5P, SMC5-AS1, RPL24P8, SMC5, AL162390.1, Y_RNA.
- chr12:44,498,616–44,503,596, 2 genes, copy number 6: AC025253.1, AC025253.2.
- chr12:57,591,174–57,626,125, 5 genes, copy number 14 (within-gene range 2–14): PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6.
- chr12:57,693,955–57,984,761, 27 genes, copy number 14: OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2.
- chr12:65,758,020–66,254,622, 14 genes, copy number 19 (within-gene range 2–19): RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3.
- chr12:66,302,493–66,343,643, 1 gene, copy number 14 (within-gene range 2–14): HELB.
- chr12:67,648,338–68,576,136, 21 genes, copy number 20: DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP.
- chr12:68,805,011–70,920,738, 45 genes, copy number 9–18: AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA.
- chr12:71,125,085–71,441,898, 1 gene, copy number 8 (within-gene range 2–15): TSPAN8.
- chr12:72,087,266–72,670,758, 1 gene, copy number 16 (within-gene range 1–16): TRHDE.
- chr12:72,431,722–74,402,600, 17 genes, copy number 16–28: H3P35, CHCHD3P2, AC133480.1, AC090503.2, LINC02444, AC090503.1, AC087879.1, RNU6-1012P, LINC02445, U8, LINC02882, AC136188.1, LINC02394, AC090502.3, AC090502.2, AC090502.1, VENTXP3.
- chr12:75,649,195–75,691,937, 1 gene, copy number 16 (within-gene range 2–16): AC078820.2.
- chr12:76,619,386–76,757,914, 4 genes, copy number 16: YWHAQP7, AC107032.1, RPL7P43, AC093014.1.
- chr12:77,324,641–78,213,010, 1 gene, copy number 24 (within-gene range 2–24): NAV3.
- chr12:77,775,783–78,808,995, 9 genes, copy number 15–24: AC138331.1, AC073571.1, PRXL2AP1, LINC02424, AC128707.1, AC130415.1, AC079362.1, AC068993.1, AC068993.2.
- chr12:78,960,258–79,045,644, 1 gene, copy number 15: AC090709.1.
- chr12:79,989,014–81,261,210, 18 genes, copy number 10–30 (within-gene range 4–30): SNRPGP20, RPL7P38, RNU7-106P, OTOGL, AC078817.1, RN7SKP261, PTPRQ, AKIRIN1P1, AC074031.1, MYF6, MYF5, LINC01490, LIN7A, MIR617, AC078886.1, MIR618, ACSS3, AC078955.1.
- chr12:81,378,042–81,556,637, 2 genes, copy number 7: AC069228.1, AC079363.1.
- chr12:82,358,528–82,497,560, 3 genes, copy number 30 (within-gene range 2–30): METTL25, AC089998.3, AC089998.4.
- chr12:83,661,009–84,294,562, 4 genes, copy number 13–19 (within-gene range 2–19): AC093025.1, AC090679.3, AC090679.2, AC090679.1.
- chr12:84,671,598–86,838,904, 12 genes, copy number 6–27 (within-gene range 1–27): AC093027.1, SLC6A15, AC128657.1, TSPAN19, LRRIQ1, ALX1, LINC02820, AC126471.1, AC137768.1, RASSF9, NTS, MGAT4C.
- chr12:96,060,024–96,485,442, 10 genes, copy number 5–16: YPEL5P3, RN7SL88P, LINC02452, ELK3, AC008149.1, AC008149.2, CDK17, RNU4-24P, AC007513.1, RN7SKP11.
- chr12:101,155,493–101,228,876, 3 genes, copy number 17: SLC5A8, RNU6-768P, AC079953.1.
- chr12:102,217,318–102,230,533, 2 genes, copy number 10: RN7SL793P, AC093023.1.
- chr12:102,809,280–103,578,947, 12 genes, copy number 14 (within-gene range 6–14): LINC00485, PAH, AC026108.1, ASCL1, AC026108.2, AC068643.1, AC068643.2, C12orf42, AC084364.1, AC084364.2, AC084364.3, LINC02401.
- chr12:127,914,707–128,068,361, 4 genes, copy number 8 (within-gene range 2–8): LINC00507, LINC00508, LINC02441, AC140121.1.
- chr12:131,949,942–132,363,348, 24 genes, copy number 12 (within-gene range 2–12): EP400, SNORA49, AC137590.1, AC137590.2, EP400P1, AC138466.5, AC138466.2, DDX51, NOC4L, AC138466.3, LINC02361, AC138466.1, GALNT9, AC138466.4, AC148477.3, AC148477.2, AC148477.5, AC148477.4, AC148477.1, AC148477.7, AC148477.10, AC148477.8, AC148477.6, AC148477.9.
- chr21:17,296,219–18,267,373, 20 genes, copy number 19 (within-gene range 2–19): AP000457.1, RNU6-113P, LINC01549, RPL39P40, RN7SL163P, CXADR, BTF3L4P1, Y_RNA, Y_RNA, BTG3, BTG3-AS1, AP000432.1, AP000432.2, C21orf91-OT1, C21orf91, AL109761.1, CHODL-AS1, RPL37P3, CHODL, AF130417.1.
- chr21:23,281,736–23,490,724, 6 genes, copy number 11: RNU2-55P, D21S2088E, EEF1A1P1, TUBAP1, Y_RNA, AP000459.1.
- chr21:23,857,081–24,192,924, 6 genes, copy number 11 (within-gene range 3–11): AP000474.2, AP000474.1, AP000477.2, AP000477.3, AP000477.1, AP000470.1.

Autosomal genes at a single copy (total copy number 1): 11,110. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
